Gene-level copy-number profile of tumor specimen TCGA-ZG-A9ND-01A from TCGA case TCGA-ZG-A9ND, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 55.9 years (20,428 days).
Specimen TCGA-ZG-A9ND-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.a33e9f09-6247-418f-aa46-56e8f6deabde.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZG-A9ND-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3da32d0e-39ec-48fb-8f7d-1813266e49e1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 8,533; copy number 2: 49,600; copy number 3: 1,673.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZG-A9ND-01A-11D-A41J-01): tumor purity 0.82, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:91,642,643–91,844,529, 3 genes: AC093298.2, PCBP2P3, AC093298.1.
- chr5:92,410,256–92,660,863, 1 gene (within-gene range 0–1): AC124854.1.
- chr5:92,823,935–93,068,669, 5 genes: AC008517.1, LDHBP3, CCT7P2, LINC02058, AC012625.1.
- chr5:94,111,720–94,176,029, 1 gene: AC117528.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 6,147. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
